Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02K, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02K-01A (Primary Tumor).

Diagnosis:

This is a metastasis of a poorly differentiated adenocarcinoma with histopathological grade G3 differentiation with extensive necrosis and peritumorous inflammation (in I), tumor-free, vascularized fatty connective tissue with a moderate chronic inflammation and with fibrosis (in II)

a medium-grade to poorly differentiated adenocarcinoma in the cecum and the ascending colon with histopathological grade G2-3 differentiation, with necroses, with ulcerations of the inner tumor surface, with carcinomatous lymphangitis, with carcinosis of blood vessels, with perineural carcinosis

with tumor infiltration of all parietal layers extending to the subserous fatty connective tissue,

with 7 regional lymph node metastases (7/20),

with peritumorous chronic recurrent concomitant inflammation

tumor-free overview sections from all designated parts of the preparation and

chronic appendicitis (in III)

According to the available section preparations, the tumor spread corresponds to a tumor stage of pT3, pN2 (7/20) pM1 (HEP), L1, V1.

Locally the carcinoma was completely removed.

Tumor classification:

ICDO-DA M-8140/3, G2-3

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: ascending colon C18.2 for 3/30/11

ICDAA Discrepancy		X

Source: NCI Genomic Data Commons file 2eb874c8-a759-4706-b5b9-3b352a440cbe (TCGA-AA-A02K.EDDCC4B3-986B-4415-B742-CF0B98EACF72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).